Somatic mutation profile of tumor specimen MBCProject_0003_T1_WES (aliquot MBCProject_0003_T1_WES_1) from CMI case MBCProject_0003, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 43.6 years (15,931 days).
Specimen MBCProject_0003_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 900d17ce-ff83-4e55-9dfb-0e59519f7b6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0003_SALIVA (Saliva), aliquot MBCProject_0003_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/339768bd-d171-47b6-b1e7-dc6d076c2dac

The open-access MAF lists 76 somatic variants for this specimen: 57 protein-altering or splice-affecting, 8 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 8, Intron 6, Nonsense Mutation 4, Frame Shift Del 4, In Frame Del 2, 5'UTR 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB11 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs761707523, COSV60355973; called by muse, mutect2, varscan2
- CCDC188 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1223308379; called by muse, mutect2, varscan2
- CD55 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs148720717; called by muse, mutect2, varscan2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- DZANK1 | c.1981G>A p.V661M (on ENST00000262547 / NM_001099407.1; = p.V468M on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/300 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.164); catalogued as rs766364620, COSV52757136; called by muse, mutect2, varscan2
- EXOC6B | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55560705; called by muse, mutect2, varscan2
- FCRL2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs1395454743, COSV63834194; called by muse, mutect2, varscan2
- FFAR3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 223/1314 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765904411; called by muse, mutect2, varscan2
- FMN2 | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); catalogued as rs142072223, COSV60444287; called by muse, mutect2, varscan2
- GPC3 | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1569458691; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF26B | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 452/618 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750881727; called by muse, mutect2, varscan2
- KRT78 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV100467085, COSV58851497; called by muse, mutect2, varscan2
- LCE5A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 209/659 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.485); catalogued as rs1423735491, COSV57500082; called by muse, mutect2, varscan2
- MYO3B | c.2686G>C p.A896P | Missense Mutation (SNP) | VAF 110/315 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.555); catalogued as rs753999476, COSV58698249; called by muse, mutect2, varscan2
- OR2M5 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 196/464 reads (42%) | catalogued as COSV63546261; called by muse, mutect2, varscan2
- PLCB1 | c.2891C>A p.A964D | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV100569348; called by muse, mutect2, varscan2
- PTEN | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV64310770; called by muse, mutect2, varscan2
- SEMA5A | c.3079A>T p.K1027* | Nonsense Mutation (SNP) | VAF 142/410 reads (35%) | catalogued as COSV66801833; called by muse, mutect2, varscan2
- SLC6A11 | c.1575G>A p.A525= | Splice Region (SNP) | VAF 42/109 reads (39%) | catalogued as rs1320790036, COSV99594405; called by muse, mutect2, varscan2
- VSTM2A | c.619_622del p.Q207Vfs*8 | Frame Shift Del (DEL) | VAF 45/168 reads (27%) | catalogued as rs1415353827; called by pindel, varscan2
- VWA7 | c.2423C>A p.A808E | Missense Mutation (SNP) | VAF 134/436 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770242653; called by muse, mutect2, varscan2
- AC231657.3 | c.665C>G p.A222G | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATAD2 | c.3613A>G p.T1205A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMK2B | c.17C>T p.T6I | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- CD109 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFTR | c.2265C>G p.I755M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNMD | c.408A>C p.Q136H | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- COBLL1 | c.2845A>C p.K949Q (on ENST00000392717; = p.K911Q on NM_014900.5) | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CPEB1 | c.40_57del p.I14_H19del | In Frame Del (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- DIPK1C | c.262_264delinsAA p.E88Nfs*62 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by pindel, varscan2*
- FRMPD4 | c.1054T>A p.S352T | Missense Mutation (SNP) | VAF 84/185 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- FSIP2 | c.13921A>T p.I4641F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- GRM4 | c.1877G>C p.S626T | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H2AC13 | c.98G>C p.R33P | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- H2AC15 | c.117C>G p.N39K | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- KCNA4 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KIF24 | c.3346T>A p.S1116T | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- KMT2C | c.8950del p.S2984Lfs*6 | Frame Shift Del (DEL) | VAF 73/274 reads (27%) | called by mutect2, pindel, varscan2
- MUC16 | c.13771A>T p.I4591F | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); called by muse, mutect2
- MUC16 | c.8957G>T p.R2986I | Missense Mutation (SNP) | VAF 127/326 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIPBL | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR4X2 | c.372C>G p.Y124* | Nonsense Mutation (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- OSGIN2 | c.1160_1209del p.K387Ifs*2 | Frame Shift Del (DEL) | VAF 65/330 reads (20%) | called by mutect2, pindel
- PDZD2 | c.3262G>T p.E1088* | Nonsense Mutation (SNP) | VAF 82/317 reads (26%) | called by muse, mutect2, varscan2
- PLXDC1 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PPFIA4 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 151/594 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- RBSN | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- SIMC1 | c.1523A>G p.H508R (on ENST00000443967 / NM_001308196.1; = p.H93R on NM_198567.5) | Missense Mutation (SNP) | VAF 124/384 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SLC6A17 | c.2107C>A p.L703M | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- THEMIS | c.1897A>G p.T633A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM176A | c.286-2A>G p.X96_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2
- UBQLN4 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 103/360 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ZFYVE28 | c.2435dup p.E813Gfs*130 | Frame Shift Ins (INS) | VAF 62/141 reads (44%) | called by mutect2, pindel, varscan2
- ZNF608 | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, varscan2
- ZNF654 | c.2898T>G p.N966K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804A | c.458_460del p.Q153del | In Frame Del (DEL) | VAF 27/71 reads (38%) | called by mutect2, pindel, varscan2
- ZXDB | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- ARRDC3 | c.828T>G p.S276= | Silent (SNP) | VAF 100/236 reads (42%) | called by muse, mutect2, varscan2
- OTOG | c.4662C>T p.P1554= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs149372486; called by muse, mutect2, varscan2
- PCDHB7 | c.1677C>G p.P559= | Silent (SNP) | VAF 388/1154 reads (34%) | called by muse, mutect2, varscan2
- PTPN7 | c.375C>T p.Y125= (on ENST00000495688; = p.Y164= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 184/337 reads (55%) | catalogued as rs746969309; called by muse, mutect2, varscan2
- S100A10 | c.93G>C p.L31= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- SALL3 | c.429C>T p.R143= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs1467425547, COSV73306407; called by muse, mutect2, varscan2
- SYT11 | c.843C>T p.I281= | Silent (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- ZMAT3 | c.579A>G p.Q193= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as rs749452113; called by muse, mutect2, varscan2
- CLDN15 | c.217+565C>T | Intron (SNP) | VAF 104/306 reads (34%) | catalogued as rs1299213567; called by muse, mutect2, varscan2
- DNAH14 | c.3052-21546A>C | Intron (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- DST | c.4296+4618del | Intron (DEL) | VAF 117/377 reads (31%) | called by mutect2, pindel, varscan2
- EXD1 | c.28+3963C>G | Intron (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- GTF3C5 | chr9:133030953 G>T | 5'Flank (SNP) | VAF 77/191 reads (40%) | catalogued as COSV100565450; called by muse, mutect2, varscan2
- OBSCN | c.4585+2792C>T | Intron (SNP) | VAF 132/616 reads (21%) | catalogued as rs369623103; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156188 G>A | 3'Flank (SNP) | VAF 135/317 reads (43%) | called by muse, mutect2, varscan2
- SETBP1 | c.540+7308C>G | Intron (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- TMC1 | c.*43G>C | 3'UTR (SNP) | VAF 59/185 reads (32%) | catalogued as rs756617297; called by muse, mutect2, varscan2
- ZNF134 | c.-181C>T | 5'UTR (SNP) | VAF 47/204 reads (23%) | called by muse, mutect2, varscan2
- ZNF324B | c.-19G>A | 5'UTR (SNP) | VAF 46/178 reads (26%) | called by muse, varscan2
